Somatic mutation profile of tumor specimen TCGA-CF-A5UA-01A (aliquot TCGA-CF-A5UA-01A-11D-A289-08) from TCGA case TCGA-CF-A5UA, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage II; Tumor grade: Low Grade; Age at diagnosis: 67.4 years (24,625 days).
Specimen TCGA-CF-A5UA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ae4dd93e-49f1-4004-9b3f-6a5863934de7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CF-A5UA-10A (Blood Derived Normal), aliquot TCGA-CF-A5UA-10A-01D-A289-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0d84bf9f-6214-4aba-bd19-467fd4725af4

The open-access MAF lists 85 somatic variants for this specimen: 58 protein-altering or splice-affecting, 24 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 52, Silent 24, Nonsense Mutation 3, Splice Site 2, Intron 2, Nonstop Mutation 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERBB2 | c.2033G>A p.R678Q | Missense Mutation (SNP) | VAF 56/135 reads (41%) | hotspot (GDC flag); SIFT tolerated (0.19); PolyPhen benign (0.103); catalogued as rs1057519862, COSV54062926; ClinVar: likely pathogenic / not provided; called by muse, mutect2, varscan2
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 18/35 reads (51%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ACSL1 | c.1439T>C p.V480A | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs752627811, COSV55666216; called by muse, mutect2, varscan2
- ADGRL2 | c.3317G>T p.G1106V (on ENST00000370717 / NM_001366005.1; = p.G1093V on NM_012302.4) | Missense Mutation (SNP) | VAF 68/150 reads (45%) | SIFT tolerated (0.29); PolyPhen benign (0.05); catalogued as COSV54686110; called by muse, mutect2, varscan2
- ADSS1 | c.982G>A p.E328K | Missense Mutation (SNP) | VAF 79/153 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.497); catalogued as rs772167104, COSV58276026; called by muse, mutect2, varscan2
- ALG10B | c.517A>G p.K173E | Missense Mutation (SNP) | VAF 88/179 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0.079); catalogued as COSV58144753; called by muse, mutect2, varscan2
- APBA2 | c.2218C>T p.L740F | Missense Mutation (SNP) | VAF 9/217 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54286291; called by muse, mutect2
- ATAD2 | c.3058G>C p.D1020H | Missense Mutation (SNP) | VAF 31/153 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54885975; called by muse, mutect2, varscan2
- CAMTA2 | c.2522C>T p.S841L | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.945); catalogued as rs1338414516, COSV52779302; called by muse, mutect2, varscan2
- CBLN4 | c.73G>T p.V25F | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV50352594, COSV99290265; called by muse, mutect2
- CCNG2 | c.652T>A p.L218M | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0.244); catalogued as COSV60354690; called by muse, mutect2, varscan2
- CD6 | c.1154C>T p.S385F | Missense Mutation (SNP) | VAF 101/224 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.744); catalogued as COSV57842163; called by muse, mutect2, varscan2
- CLIP2 | c.98C>T p.A33V | Missense Mutation (SNP) | VAF 98/287 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs142367137, COSV99791592; called by muse, mutect2, varscan2
- CYP2A7 | c.1114C>T p.R372C | Missense Mutation (SNP) | VAF 59/190 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs151290022; called by muse, mutect2, varscan2
- DNAH1 | c.4705G>A p.G1569R | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs758847297, COSV101326477, COSV70235363; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAJC10 | c.652G>A p.G218R | Missense Mutation (SNP) | VAF 58/131 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV51135623, COSV51145987; called by muse, mutect2, varscan2
- DYNLT1 | c.341G>C p.*114Sext*49 | Nonstop Mutation (SNP) | VAF 6/19 reads (32%) | catalogued as COSV100892376; called by muse, mutect2, varscan2
- EML5 | c.3036C>G p.I1012M | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.707); catalogued as COSV61351578; called by muse, mutect2, varscan2
- FBXO21 | c.137C>G p.S46W | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.257); catalogued as COSV100401531; called by muse, mutect2
- GALNT2 | c.877C>T p.R293W | Missense Mutation (SNP) | VAF 35/111 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773042550, COSV64197249; called by muse, mutect2, varscan2
- IL6ST | c.1462G>A p.E488K | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV61142767; called by muse, mutect2, varscan2
- IQCH | c.347G>T p.R116I | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.037); catalogued as COSV60059211; called by muse, mutect2, varscan2
- ITGA2B | c.1951G>A p.G651S | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.519); catalogued as rs868075402, COSV52234829; called by muse, mutect2, varscan2
- KBTBD11 | c.757G>A p.D253N | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.103); catalogued as rs1240610202, COSV57224738; called by muse, mutect2, varscan2
- KBTBD11 | c.1258G>A p.E420K | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1373769388, COSV100207481; called by muse, mutect2, varscan2
- KCNC2 | c.1480A>G p.K494E | Missense Mutation (SNP) | VAF 34/44 reads (77%) | SIFT deleterious (0.01); PolyPhen benign (0.046); catalogued as COSV54378382; called by muse, mutect2, varscan2
- KIF12 | c.1081C>T p.R361* (on ENST00000640217; = p.R223* on NM_138424.1) | Nonsense Mutation (SNP) | VAF 35/80 reads (44%) | catalogued as rs757380683, COSV100936005; called by muse, mutect2, varscan2
- KREMEN1 | c.850G>A p.G284R (on ENST00000407188; = p.G286R on NM_032045.5) | Missense Mutation (SNP) | VAF 40/81 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.101); catalogued as rs751542642, COSV59911527; called by muse, mutect2, varscan2
- KRT2 | c.1651G>A p.G551S | Missense Mutation (SNP) | VAF 156/745 reads (21%) | SIFT tolerated (0.6); PolyPhen benign (0.394); catalogued as rs1247684905, COSV59009057, COSV59012504; called by muse, mutect2, varscan2
- LTBP3 | c.1015G>A p.A339T | Missense Mutation (SNP) | VAF 40/123 reads (33%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs757124780, COSV57243740; called by muse, mutect2, varscan2
- MDM1 | c.1976G>C p.G659A | Missense Mutation (SNP) | VAF 14/426 reads (3%) | SIFT tolerated (0.17); PolyPhen benign (0.049); catalogued as COSV57448665; called by muse, mutect2
- MDM1 | c.1855C>G p.P619A | Missense Mutation (SNP) | VAF 56/1899 reads (3%) | SIFT tolerated (0.51); PolyPhen benign (0.225); catalogued as COSV57447636, COSV57448676; called by muse, mutect2
- MPPED2 | c.22C>G p.Q8E | Missense Mutation (SNP) | VAF 33/37 reads (89%) | SIFT tolerated (0.34); PolyPhen benign (0.006); catalogued as COSV63900896; called by muse, mutect2, varscan2
- MRGPRF | c.759C>G p.I253M | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV57996427; called by muse, mutect2, varscan2
- MSH4 | c.1184C>G p.T395R | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); catalogued as COSV54210821; called by muse, mutect2, varscan2
- MTA1 | c.1334G>T p.R445L | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.52); catalogued as COSV58756839; called by muse, mutect2, varscan2
- MTHFD1L | c.2276G>A p.G759D | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1353930821, COSV66227267; called by mutect2, varscan2
- NCKAP1L | c.796C>G p.L266V | Missense Mutation (SNP) | VAF 43/238 reads (18%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.997); catalogued as COSV53211700, COSV53211929; called by muse, mutect2, varscan2
- NDUFS7 | c.96G>C p.Q32H | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV52041115; called by muse, mutect2
- NRP1 | c.2632G>A p.V878M | Missense Mutation (SNP) | VAF 95/172 reads (55%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.957); catalogued as rs200330871, COSV55176377; called by muse, mutect2, varscan2
- PCDH1 | c.763G>A p.G255S | Missense Mutation (SNP) | VAF 37/65 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54618850; called by muse, mutect2, varscan2
- PCDH15 | c.1892T>A p.V631D | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as COSV100212884, COSV100215117; called by muse, mutect2
- PIGQ | c.2131C>T p.P711S | Missense Mutation (SNP) | VAF 34/76 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV50319997; called by muse, varscan2
- PIK3CA | c.223C>G p.Q75E | Missense Mutation (SNP) | VAF 53/161 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.604); catalogued as COSV55924765; called by muse, mutect2, varscan2
- PKD2L1 | c.2007+1G>T p.X669_splice | Splice Site (SNP) | VAF 57/132 reads (43%) | catalogued as COSV58398503; called by muse, mutect2, varscan2
- PNLIPRP1 | c.44C>A p.A15D | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.467); catalogued as COSV62613269; called by muse, mutect2, varscan2
- PPFIA2 | c.608C>T p.S203F | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV61051785; called by muse, mutect2, varscan2
- SLC24A1 | c.1642C>T p.R548* | Nonsense Mutation (SNP) | VAF 70/199 reads (35%) | catalogued as rs761148442, COSV99977935; called by muse, mutect2, varscan2
- SMG8 | c.2409G>C p.R803S | Missense Mutation (SNP) | VAF 78/168 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.124); catalogued as COSV56286811; called by muse, mutect2, varscan2
- TFAP2D | c.49G>T p.D17Y | Missense Mutation (SNP) | VAF 39/148 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV50435130, COSV50451424; called by muse, mutect2, varscan2
- TLX1 | c.799G>A p.E267K | Missense Mutation (SNP) | VAF 68/156 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as COSV64622827; called by muse, mutect2, varscan2
- TMTC2 | c.1808G>T p.S603I | Missense Mutation (SNP) | VAF 31/44 reads (70%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as COSV58282332; called by muse, mutect2, varscan2
- TNPO3 | c.553-1G>T p.X185_splice | Splice Site (SNP) | VAF 30/80 reads (38%) | catalogued as COSV55286178; called by muse, mutect2, varscan2
- TRPC7 | c.1519G>A p.V507M | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.575); catalogued as rs773570421, COSV61462996; called by muse, mutect2, varscan2
- TRPV5 | c.217C>T p.R73* | Nonsense Mutation (SNP) | VAF 40/105 reads (38%) | catalogued as rs778703315, COSV54683831; called by muse, mutect2, varscan2
- WDPCP | c.1586A>C p.N529T | Missense Mutation (SNP) | VAF 43/88 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV55430935; called by muse, mutect2, varscan2
- ZNF319 | c.175G>A p.G59S | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT tolerated (0.93); PolyPhen benign (0.003); catalogued as rs752156059, COSV54623507, COSV54623776; called by muse, mutect2, varscan2
- ZNF554 | c.332G>A p.S111N | Missense Mutation (SNP) | VAF 92/187 reads (49%) | SIFT deleterious (0.05); PolyPhen benign (0.074); catalogued as COSV57886846; called by muse, mutect2, varscan2
- AGRN | c.861C>T p.S287= | Silent (SNP) | VAF 5/9 reads (56%) | catalogued as COSV101038464; called by muse, mutect2, varscan2
- AMY1C | c.984T>A p.L328= | Silent (SNP) | VAF 101/842 reads (12%) | catalogued as COSV64407466; called by muse, mutect2, varscan2
- ARMC2 | c.1995G>C p.V665= | Silent (SNP) | VAF 38/93 reads (41%) | catalogued as COSV64553062; called by muse, mutect2, varscan2
- ATP13A1 | c.327C>A p.L109= | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as COSV52290787; called by muse, mutect2, varscan2
- C9 | c.1287A>C p.I429= | Silent (SNP) | VAF 29/125 reads (23%) | catalogued as COSV54680934; called by muse, mutect2, varscan2
- CPSF4 | c.147C>T p.C49= | Silent (SNP) | VAF 112/234 reads (48%) | catalogued as rs759412959, COSV52859052; called by muse, mutect2, varscan2
- FAM171B | c.1386C>T p.I462= | Silent (SNP) | VAF 19/68 reads (28%) | catalogued as COSV59008059; called by muse, mutect2, varscan2
- FRG2C | c.657T>C p.C219= | Silent (SNP) | VAF 26/192 reads (14%) | called by muse, mutect2, varscan2
- GABRB1 | c.429G>T p.L143= | Silent (SNP) | VAF 45/217 reads (21%) | catalogued as COSV54997830; called by muse, mutect2, varscan2
- GRM7 | c.345G>A p.A115= | Silent (SNP) | VAF 44/85 reads (52%) | catalogued as COSV63167243; called by muse, mutect2, varscan2
- IRAG1 | c.1956G>A p.A652= | Silent (SNP) | VAF 107/119 reads (90%) | catalogued as rs540632213, COSV70209722; called by muse, mutect2, varscan2
- IRX1 | c.1131C>T p.S377= | Silent (SNP) | VAF 22/81 reads (27%) | catalogued as COSV57362148; called by muse, mutect2, varscan2
- ITGB8 | c.1776C>T p.H592= | Silent (SNP) | VAF 26/57 reads (46%) | catalogued as COSV56013730; called by muse, mutect2, varscan2
- NLRP7 | c.1407C>T p.L469= | Silent (SNP) | VAF 37/110 reads (34%) | catalogued as COSV60181177; called by muse, mutect2, varscan2
- OR1S1 | c.108T>C p.H36= | Silent (SNP) | VAF 57/137 reads (42%) | catalogued as COSV58708472; called by muse, mutect2, varscan2
- PHF13 | c.876G>A p.T292= | Silent (SNP) | VAF 23/77 reads (30%) | catalogued as rs1257573874, COSV50011689; called by muse, mutect2, varscan2
- PIGQ | c.2208C>T p.P736= | Silent (SNP) | VAF 44/108 reads (41%) | catalogued as COSV50320045; called by muse, varscan2
- PNLIPRP1 | c.45C>A p.A15= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as COSV62613285; called by muse, mutect2, varscan2
- SLC52A3 | c.384G>A p.P128= | Silent (SNP) | VAF 20/55 reads (36%) | catalogued as rs774162429, COSV54079105; called by muse, mutect2, varscan2
- TAMALIN | c.777C>T p.F259= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as rs766979803, COSV99530951; called by muse, varscan2
- TMEM37 | c.213C>A p.I71= | Silent (SNP) | VAF 43/118 reads (36%) | catalogued as COSV50031241; called by mutect2, varscan2
- TNFAIP3 | c.1341G>A p.A447= | Silent (SNP) | VAF 33/76 reads (43%) | catalogued as rs745670694, COSV52800820, COSV52802684; called by muse, mutect2, varscan2
- UTP14A | c.525C>G p.L175= | Silent (SNP) | VAF 36/44 reads (82%) | catalogued as COSV64087818; called by muse, mutect2, varscan2
- VGLL2 | c.606G>A p.A202= | Silent (SNP) | VAF 12/20 reads (60%) | catalogued as rs757785717, COSV58310089; called by muse, varscan2
- ARHGAP39 | c.2522-3531G>C | Intron (SNP) | VAF 53/291 reads (18%) | catalogued as COSV52775254; called by muse, mutect2, varscan2
- DIXDC1 | c.656+2801C>T | Intron (SNP) | VAF 3/10 reads (30%) | catalogued as COSV100179990; called by muse, mutect2
- SSPOP | n.10969C>T | RNA (SNP) | VAF 39/88 reads (44%) | catalogued as rs554936166, COSV100946869, COSV100947375; called by muse, mutect2, varscan2
